Somatic mutation profile of tumor specimen TCGA-DX-A1KW-01A (aliquot TCGA-DX-A1KW-01A-22D-A24N-09) from TCGA case TCGA-DX-A1KW, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Dedifferentiated liposarcoma; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 67.5 years (24,647 days).
Specimen TCGA-DX-A1KW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 13831daa-3e3b-4207-9caa-d11a2e16b577.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DX-A1KW-10A (Blood Derived Normal), aliquot TCGA-DX-A1KW-10A-01D-A24N-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5ab55392-393f-4ec2-9b57-abb997d58e06

The open-access MAF lists 39 somatic variants for this specimen: 29 protein-altering or splice-affecting, 9 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, Silent 9, Intron 1, Splice Region 1, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DACH2 | c.593C>T p.T198I | Missense Mutation (SNP) | VAF 20/27 reads (74%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV64190197; called by muse, mutect2, varscan2
- DOCK2 | c.4511C>T p.T1504M | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as rs201320169, COSV56944226; called by muse, mutect2, varscan2
- FBN3 | c.4745C>T p.T1582M | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.975); catalogued as rs372444818, COSV54469090; called by muse, mutect2, varscan2
- GP6 | c.698C>G p.S233* | Nonsense Mutation (SNP) | VAF 17/61 reads (28%) | catalogued as COSV59977599; called by muse, mutect2, varscan2
- GPRIN1 | c.820G>A p.A274T | Missense Mutation (SNP) | VAF 37/60 reads (62%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as rs779938807, COSV104381289; called by muse, mutect2, varscan2
- H3C2 | c.80G>C p.R27P | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.522); catalogued as COSV52518963, COSV99451494; called by muse, mutect2
- ITSN1 | c.3142G>A p.G1048R | Missense Mutation (SNP) | VAF 46/124 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as rs1440104219, COSV66081911; called by muse, mutect2, varscan2
- LY75 | c.2191C>T p.R731C | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.606); catalogued as rs1255735605, COSV55104210; called by mutect2, varscan2
- MAP1A | c.1919C>T p.A640V | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.185); catalogued as rs754398083; called by muse, varscan2
- MAPK6 | c.1286A>T p.D429V | Missense Mutation (SNP) | VAF 42/68 reads (62%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.708); catalogued as rs1156300038; called by muse, mutect2, varscan2
- NUP188 | c.749A>G p.N250S | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.981); catalogued as rs747280522; called by muse, mutect2, varscan2
- SCNN1B | c.1784C>T p.A595V | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs926712911, COSV56301349; called by muse, mutect2
- SYNE1 | c.23734A>G p.I7912V (on ENST00000367255 / NM_182961.4; = p.I7841V on NM_033071.3) | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.866); catalogued as rs775744468; called by muse, mutect2, varscan2
- AFP | c.138G>C p.L46= | Splice Region (SNP) | VAF 13/47 reads (28%) | called by muse, mutect2, varscan2
- AHCTF1 | c.2252G>A p.G751E (on ENST00000366508; = p.G725E on NM_015446.5) | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANK3 | c.775G>T p.A259S | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2
- AP3D1 | c.772A>G p.K258E | Missense Mutation (SNP) | VAF 52/115 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ASAH2 | c.1571T>C p.V524A | Missense Mutation (SNP) | VAF 80/135 reads (59%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.814); called by muse, mutect2, varscan2
- CLEC1A | c.437A>G p.D146G | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- FLRT2 | c.1366A>C p.K456Q | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- HUNK | c.2056C>A p.P686T | Missense Mutation (SNP) | VAF 5/84 reads (6%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.001); called by muse, mutect2
- MACO1 | c.193G>T p.V65F | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- MYLK3 | c.1318G>T p.V440F | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- RBAK | c.475A>G p.R159G | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, mutect2, varscan2
- RPL41 | c.56A>T p.K19M | Missense Mutation (SNP) | VAF 45/67 reads (67%) | called by muse, mutect2, varscan2
- TMEM150B | c.602T>G p.V201G | Missense Mutation (SNP) | VAF 52/113 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- TNS3 | c.2302del p.L768Wfs*8 | Frame Shift Del (DEL) | VAF 6/21 reads (29%) | called by mutect2, pindel, varscan2
- ZC3H12C | c.1873G>A p.D625N | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- ZNF443 | c.1009T>C p.Y337H | Missense Mutation (SNP) | VAF 54/227 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.612); called by muse, mutect2, varscan2
- CDH7 | c.633C>A p.I211= | Silent (SNP) | VAF 10/35 reads (29%) | catalogued as COSV59886915; called by muse, mutect2, varscan2
- DIP2B | c.3891C>T p.S1297= | Silent (SNP) | VAF 105/837 reads (13%) | catalogued as rs866225256, COSV56581673; called by muse, mutect2, varscan2
- DPP6 | c.1620C>T p.S540= (on ENST00000377770 / NM_001364500.2; = p.S478= on NM_001936.5) | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as rs369843983, COSV100127928; called by muse, varscan2
- ELOA | c.1254G>A p.E418= | Silent (SNP) | VAF 8/27 reads (30%) | called by mutect2, varscan2
- LRP1B | c.4467C>G p.T1489= | Silent (SNP) | VAF 49/105 reads (47%) | called by muse, mutect2, varscan2
- OCM2 | c.282A>C p.G94= | Silent (SNP) | VAF 30/94 reads (32%) | called by muse, mutect2, varscan2
- OR5H1 | c.519A>T p.I173= | Silent (SNP) | VAF 20/61 reads (33%) | catalogued as rs949186743, COSV63402972; called by muse, mutect2, varscan2
- TRAFD1 | c.837C>T p.L279= | Silent (SNP) | VAF 21/323 reads (7%) | called by muse, mutect2
- TTN | c.4731C>T p.V1577= (on ENST00000591111; = p.V1531= on NM_003319.4) | Silent (SNP) | VAF 16/51 reads (31%) | called by muse, mutect2, varscan2
- NSD2 | c.3373-205C>T | Intron (SNP) | VAF 21/114 reads (18%) | catalogued as COSV100373368; called by muse, mutect2, varscan2
